Somatic mutation profile of tumor specimen TCGA-CM-4747-01A (aliquot TCGA-CM-4747-01A-01D-1408-10) from TCGA case TCGA-CM-4747, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IVA; Age at diagnosis: 47.1 years (17,198 days).
Specimen TCGA-CM-4747-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 053c27a6-dfd4-432e-8a3f-dc73417950cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-4747-10A (Blood Derived Normal), aliquot TCGA-CM-4747-10A-01D-1408-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c6fbfcd-f827-4a21-a149-56cef76c8530

The open-access MAF lists 105 somatic variants for this specimen: 65 protein-altering or splice-affecting, 38 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 38, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 2, 3'UTR 1, Frame Shift Ins 1, Splice Region 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 37/88 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1625A>C p.E542A | Missense Mutation (SNP) | VAF 30/164 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as rs782569374, COSV54357935; called by muse, mutect2, varscan2
- AGPAT5 | c.744G>A p.T248= | Splice Region (SNP) | VAF 15/42 reads (36%) | catalogued as rs759275067, COSV53448777; called by muse, mutect2, varscan2
- APH1B | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs754872268, COSV56014447; called by muse, mutect2, varscan2
- ASH1L | c.3169A>T p.T1057S | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1558148991, COSV100853561; called by muse, mutect2
- ASMTL | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV67244899; called by muse, mutect2, varscan2
- CACNA2D4 | c.1816G>T p.A606S | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV54957080; called by muse, mutect2, varscan2
- CARD11 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs992263343, COSV67797100; ClinVar: uncertain significance; called by muse, varscan2
- COL18A1 | c.3402+1G>A p.X1134_splice (on ENST00000359759 / NM_130444.3; = p.X899_splice on NM_030582.4) | Splice Site (SNP) | VAF 8/53 reads (15%) | catalogued as rs1409030092, COSV60592364; called by muse, mutect2, varscan2
- CYP8B1 | c.315dup p.L106Tfs*16 | Frame Shift Ins (INS) | VAF 19/127 reads (15%) | catalogued as rs756219667; called by mutect2, varscan2
- DISP2 | c.3184G>A p.A1062T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1378876819, COSV51135918; called by muse, mutect2, varscan2
- EPRS1 | c.3235C>T p.P1079S | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65100885; called by muse, mutect2, varscan2
- FLG2 | c.6205C>G p.H2069D | Missense Mutation (SNP) | VAF 54/283 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV101166092; called by muse, mutect2, varscan2
- FRY | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs779292401, COSV66564585; called by muse, mutect2, varscan2
- HLA-DPA1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs770307009, COSV70089438; called by muse, mutect2, varscan2
- ISG20L2 | c.682A>G p.R228G | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57461080; called by muse, mutect2, varscan2
- ITK | c.39G>T p.K13N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101439896, COSV70064615; called by muse, mutect2, varscan2
- JADE2 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.207); catalogued as rs746421512, COSV50926444; called by muse, mutect2, varscan2
- KCNA5 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.187); catalogued as COSV52907895; called by muse, mutect2, varscan2
- KDM6A | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65043944; called by muse, mutect2, varscan2
- KMT2D | c.5129C>T p.T1710M | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs587778457, COSV56471735, COSV56472977; ClinVar: not provided; called by muse, mutect2, varscan2
- LAMTOR2 | c.177C>G p.N59K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as COSV100849116; called by mutect2, varscan2
- LHFPL5 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs771631412, COSV100799005; called by muse, mutect2, varscan2
- LOXL4 | c.161G>A p.W54* | Nonsense Mutation (SNP) | VAF 11/59 reads (19%) | catalogued as COSV53258676; called by muse, mutect2, varscan2
- LRP1B | c.9026C>T p.S3009L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs558778727, COSV67200762; called by muse, mutect2, varscan2
- MAGI2 | c.1148C>A p.A383E | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62687381, COSV62707813; called by muse, mutect2, varscan2
- MYH3 | c.3593C>T p.A1198V | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs374929326; called by muse, mutect2, varscan2
- NCAM1 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV57514443; called by muse, mutect2, varscan2
- NOX1 | c.1259A>G p.K420R | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.107); catalogued as COSV54196120; called by muse, mutect2, varscan2
- NVL | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.943); catalogued as rs772843150, COSV55875118; called by muse, mutect2, varscan2
- OR2T27 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs373763934, COSV100788345; called by muse, mutect2, varscan2
- PCDHB3 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.315); catalogued as rs781818511, COSV50610018; called by muse, mutect2, varscan2
- PCDHB4 | c.947T>C p.V316A | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs1554274444, COSV99522412; called by muse, mutect2
- PCDHB7 | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.422); catalogued as rs782137017, COSV50757033; called by muse, mutect2
- PLCE1 | c.5147T>G p.F1716C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.312); catalogued as COSV99596520; called by muse, mutect2, varscan2
- PLSCR4 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61608802; called by muse, mutect2, varscan2
- PTDSS1 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV61264429; called by muse, mutect2
- QSER1 | c.2237G>A p.G746D (on ENST00000399302; = p.G875D on NM_001076786.3) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV67901454; called by muse, mutect2, varscan2
- RAB26 | c.668+2dup p.X223_splice | Splice Site (INS) | VAF 10/51 reads (20%) | catalogued as rs756453356; called by mutect2, pindel, varscan2
- RAC2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as rs758461304, COSV99969611; ClinVar: likely benign; called by muse, mutect2
- RIMBP2 | c.1046G>A p.R349K | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); catalogued as COSV99900160; called by muse, mutect2, varscan2
- SLC25A31 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as rs374027476; called by muse, mutect2, varscan2
- SLITRK6 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1201478731, COSV68391234; called by muse, mutect2, varscan2
- SMURF1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.996); catalogued as COSV63156006; called by muse, mutect2, varscan2
- SNPH | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs771345502, COSV67871539; called by muse, mutect2, varscan2
- SOCS6 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs769812956, COSV67546963; called by muse, mutect2, varscan2
- SPATA13 | c.1274A>G p.K425R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1205426761, COSV100542466; called by muse, mutect2, varscan2
- SPATA31D1 | c.1310C>A p.S437* | Nonsense Mutation (SNP) | VAF 57/110 reads (52%) | catalogued as COSV61199721; called by muse, mutect2, varscan2
- SRMS | c.1459C>T p.H487Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs146373271; called by muse, mutect2, varscan2
- SSTR4 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as rs750847560, COSV54799603; called by muse, mutect2, varscan2
- SULF1 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs144030540; called by muse, mutect2, varscan2
- TMEM213 | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV100023491; called by muse, mutect2
- TRIO | c.3953A>T p.Y1318F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.985); catalogued as COSV100710785, COSV60097888; called by muse, mutect2
- TRPS1 | c.3758C>T p.T1253M (on ENST00000220888 / NM_001330599.2; = p.T1266M on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/228 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs376875568; called by muse, mutect2, varscan2
- UROC1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.284); catalogued as rs143782037; called by muse, mutect2, varscan2
- WIPF3 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs754655046, COSV54210700; called by muse, mutect2, varscan2
- ZDHHC12 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as rs1406090729, COSV52579077; called by muse, mutect2, varscan2
- ZNF114 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs1365839598, COSV100252131; called by muse, mutect2, varscan2
- ZNF568 | c.692del p.F231Sfs*151 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | catalogued as COSV100451134; called by mutect2, pindel, varscan2
- ZNF639 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV58384019; called by muse, mutect2, varscan2
- ZNF804A | c.2690A>C p.H897P | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56464542; called by muse, mutect2, varscan2
- ZSCAN4 | c.942T>A p.C314* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV99990199; called by muse, mutect2
- BTN2A2 | c.507_517del p.C169Wfs*16 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- RHBDD3 | c.70_72del p.L24del | In Frame Del (DEL) | VAF 14/46 reads (30%) | called by pindel, varscan2
- ADCY9 | c.3312C>T p.I1104= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs759735634, COSV53573727; called by muse, mutect2, varscan2
- AGA | c.210C>T p.D70= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs762870187, COSV99219655; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARC | c.780C>T p.S260= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs770283075, COSV63079295; called by muse, mutect2, varscan2
- BLM | c.360C>T p.C120= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV61926381; called by muse, mutect2, varscan2
- CCNE1 | c.1188G>A p.P396= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs754411380, COSV52905336; called by muse, mutect2, varscan2
- CD226 | c.651G>A p.S217= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs207476919, COSV54614377; called by muse, mutect2, varscan2
- CD86 | c.540C>T p.I180= (on ENST00000330540 / NM_175862.5; = p.I174= on NM_006889.4) | Silent (SNP) | VAF 49/110 reads (45%) | catalogued as rs780454711, COSV52608229; called by muse, mutect2, varscan2
- COL4A2 | c.4440T>C p.G1480= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV64632281; called by muse, mutect2, varscan2
- CTTNBP2 | c.4080C>T p.G1360= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs757314897, COSV50448349; called by muse, mutect2, varscan2
- CYP1B1 | c.681C>T p.H227= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99572798; called by muse, mutect2
- DNMT3B | c.219T>C p.D73= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV99142996; called by muse, mutect2
- DPEP3 | c.1137G>A p.L379= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV52052422; called by muse, mutect2, varscan2
- FAT3 | c.8091C>T p.H2697= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as rs765879241, COSV53156827, COSV53160947; called by muse, mutect2, varscan2
- H2BW1 | c.126G>T p.L42= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV54221082; called by muse, mutect2, varscan2
- ISM1 | c.555C>T p.D185= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs377766422; called by muse, mutect2, varscan2
- KCNT1 | c.3045C>T p.A1015= (on ENST00000488444; = p.A1034= on NM_020822.3) | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1176639976, COSV53699259; called by muse, mutect2, varscan2
- MROH9 | c.711C>T p.D237= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs377151868; called by muse, mutect2, varscan2
- MUC16 | c.43416C>T p.C14472= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs189237583; called by muse, mutect2, varscan2
- MUC16 | c.32478G>A p.T10826= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs774569415, COSV67469407; called by muse, mutect2, varscan2
- MYG1 | c.651C>T p.F217= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- MYO18B | c.327C>T p.S109= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs367932319; called by muse, mutect2, varscan2
- NLRP1 | c.3174C>T p.C1058= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1397225075, COSV52565814; called by muse, mutect2, varscan2
- PAXBP1 | c.864G>A p.E288= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as COSV51611468; called by muse, mutect2, varscan2
- PCDHA13 | c.1785C>T p.R595= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs782043806, COSV56521650; called by muse, mutect2, varscan2
- PCDHB6 | c.1335C>T p.N445= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as rs1554277740, COSV50689781; called by muse, mutect2, varscan2
- PCDHB7 | c.1398C>T p.P466= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as rs782335891, COSV50802585; called by muse, mutect2, varscan2
- PCNX2 | c.6375C>T p.D2125= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs748910691, COSV50853194; called by muse, mutect2, varscan2
- PLXNB1 | c.4062A>G p.E1354= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV56493018; called by muse, mutect2, varscan2
- SPACA5B | c.276C>T p.T92= | Silent (SNP) | VAF 68/353 reads (19%) | catalogued as COSV100422427; called by muse, mutect2, varscan2
- STAP1 | c.495T>G p.T165= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV55329470; called by muse, mutect2, varscan2
- TIGD7 | c.300C>T p.G100= | Silent (SNP) | VAF 58/137 reads (42%) | catalogued as rs547017663, COSV51916676; called by muse, mutect2, varscan2
- TRIM42 | c.498C>T p.C166= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs756270365, COSV53879972; called by muse, mutect2, varscan2
- TRIM42 | c.1467C>T p.L489= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV53885745; called by muse, mutect2, varscan2
- TTC30A | c.300G>A p.R100= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99614128; called by muse, mutect2
- VTA1 | c.30C>T p.L10= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs750897371, COSV62660014; called by muse, mutect2, varscan2
- ZFHX4 | c.1839C>T p.I613= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs371449494, COSV50930139; called by muse, mutect2, varscan2
- ZKSCAN3 | c.183C>T p.R61= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs749140174, COSV52853879; called by muse, mutect2, varscan2
- ZNF254 | c.696T>C p.Y232= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs1464466488, COSV61644213; called by muse, mutect2, varscan2
- CNIH3 | c.*2G>A | 3'UTR (SNP) | VAF 14/35 reads (40%) | catalogued as rs763926613, COSV99686169, COSV99686270; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397375 C>T | 3'Flank (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
